Somatic mutation profile of tumor specimen MP2PRT-PASVCX-TMP1-A (aliquot MP2PRT-PASVCX-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASVCX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (959 days).
Specimen MP2PRT-PASVCX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0ba2bb2-b501-47cc-8320-083cbea4f1a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASVCX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASVCX-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b993c82c-7623-44d1-b79b-bc780e9b83a6

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 113/268 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SCD | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 221/500 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261617778; called by muse, mutect2, varscan2
- SQSTM1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 159/357 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs368853286, CM152701; called by muse, mutect2, varscan2
- TMEM242 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 247/557 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.293); catalogued as rs868955517, COSV65653985; called by muse, mutect2, varscan2
- TPM1 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 136/306 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1266444831; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBD | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 60/681 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100589683; called by muse, mutect2
- CDH2 | c.1182C>A p.N394K | Missense Mutation (SNP) | VAF 128/296 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- HMGN5 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 284/303 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TIGD2 | c.632_633insGG p.I211Mfs*38 | Frame Shift Ins (INS) | VAF 127/361 reads (35%) | called by mutect2, pindel, varscan2
- CCDC38 | c.819C>T p.S273= | Silent (SNP) | VAF 107/248 reads (43%) | catalogued as rs375612160, COSV100717841; called by muse, mutect2
- GRHL3 | c.1029C>T p.N343= (on ENST00000350501 / NM_198174.3; = p.N348= on NM_021180.3) | Silent (SNP) | VAF 124/302 reads (41%) | catalogued as rs370453658; called by muse, mutect2, varscan2
- NAT10 | c.2109C>T p.A703= | Silent (SNP) | VAF 160/396 reads (40%) | catalogued as rs779738249; called by muse, mutect2, varscan2
